Somatic mutation profile of tumor specimen MP2PRT-PATIAN-TMP1-A (aliquot MP2PRT-PATIAN-TMP1-A-1-0-D-A82L-36) from MP2PRT case MP2PRT-PATIAN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 4.7 years (1,700 days).
Specimen MP2PRT-PATIAN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) abee1b54-1332-4e58-8452-d0faf7318a71.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATIAN-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATIAN-NB1-A-1-0-D-A82L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ac941f9-5659-48d0-a68f-3d23d9c7368e

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 10, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.1775T>C p.V592A | Missense Mutation (SNP) | VAF 46/233 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as rs1057520025, COSV54051432, COSV54058572, COSV54074139; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ANGPTL8 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 90/356 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754255586; called by muse, mutect2, varscan2
- MROH5 | c.1738G>A p.A580T | Missense Mutation (SNP) | VAF 70/375 reads (19%) | SIFT tolerated (0.73); PolyPhen benign (0.005); catalogued as rs1192272096; called by muse, mutect2, varscan2
- PNLIPRP3 | c.1228G>A p.V410I | Missense Mutation (SNP) | VAF 14/348 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.089); catalogued as COSV65049006; called by muse, mutect2
- RBFOX1 | c.293C>T p.T98M | Missense Mutation (SNP) | VAF 100/327 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs373077021; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC37A1 | c.1412C>T p.T471M | Missense Mutation (SNP) | VAF 49/558 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs771928444, COSV61402785; called by muse, mutect2
- UNC79 | c.2699C>A p.S900Y (on ENST00000393151 / NM_001346218.2; = p.S723Y on NM_020818.5) | Missense Mutation (SNP) | VAF 95/353 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV56392818; called by muse, mutect2, varscan2
- DOCK11 | c.983T>C p.L328P | Missense Mutation (SNP) | VAF 13/228 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.53); called by muse, mutect2
- GDPGP1 | c.985A>G p.N329D | Missense Mutation (SNP) | VAF 110/441 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MAZ | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 49/158 reads (31%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TXNDC2 | c.1608A>G p.E536= (on ENST00000306084 / NM_001098529.2; = p.E469= on NM_032243.6) | Silent (SNP) | VAF 94/461 reads (20%) | called by muse, mutect2
- UNC13C | c.5262T>C p.N1754= | Silent (SNP) | VAF 20/234 reads (9%) | called by muse, mutect2
